Somatic mutation profile of tumor specimen TCGA-EA-A3HU-01A (aliquot TCGA-EA-A3HU-01A-11D-A20U-09) from TCGA case TCGA-EA-A3HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 43.6 years (15,909 days).
Specimen TCGA-EA-A3HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4ec042f-f66b-4f2c-ab0c-498b48a41683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3HU-10B (Blood Derived Normal), aliquot TCGA-EA-A3HU-10B-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/324516a1-fa22-469b-ad77-ca0ead596660

The open-access MAF lists 1,210 somatic variants for this specimen: 891 protein-altering or splice-affecting, 291 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 725, Silent 291, Frame Shift Del 74, Nonsense Mutation 49, Frame Shift Ins 14, Intron 13, Splice Site 10, Splice Region 9, In Frame Del 8, RNA 7, 3'Flank 3, 3'UTR 2.

Variants (750 of 1,210; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.3713del p.K1238Rfs*6 | Frame Shift Del (DEL) | VAF 31/114 reads (27%) | catalogued as rs1557362198; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F9 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as rs137852248, CM940592, CM940593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.678-1G>A p.X226_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as rs267607784, CS056763, CS994671, COSV51618383, COSV51624593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPTOR | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs767783333, COSV60807635; called by muse, mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- A3GALT2 | c.235del p.A79Lfs*27 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs770563385; called by mutect2, pindel
- ABCA9 | c.638T>A p.L213* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs1422079545; called by muse, mutect2, varscan2
- ABCF2 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55186453; called by muse, mutect2, varscan2
- AC013489.1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs1241669470, COSV51551272; called by muse, mutect2, varscan2
- ACER1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100034019; called by muse, mutect2
- ACOX3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760846643; called by muse, mutect2, varscan2
- ACSM2B | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61658092; called by muse, mutect2, varscan2
- ACSS1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs375554533, COSV104405289; called by muse, mutect2, varscan2
- ACTL7B | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1243349202, COSV65927690; called by muse, mutect2, varscan2
- ADAM19 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs781195573, COSV99977124; called by muse, mutect2, varscan2
- ADAMTS13 | c.2716G>A p.V906I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1554792422, COSV63023679; called by muse, mutect2, varscan2
- ADAMTS19 | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs747600290, COSV50796775; called by muse, mutect2, varscan2
- ADAMTS20 | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746900088, COSV67129457; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848dup p.H950Pfs*13 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | catalogued as rs1022557002; called by mutect2, varscan2
- AGBL5 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.403); catalogued as rs779110735, COSV59937195; called by muse, mutect2, varscan2
- AIDA | c.697T>A p.L233I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV60663209; called by muse, mutect2, varscan2
- ALAS2 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748347802; called by muse, mutect2, varscan2
- ALK | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as rs1431784023; called by muse, mutect2, varscan2
- AMPD2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs764075553; called by muse, mutect2, varscan2
- ANLN | c.1575T>A p.F525L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99732448; called by muse, mutect2, varscan2
- ANO3 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99885927; called by muse, mutect2, varscan2
- ANO8 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236937826, COSV50179233; called by muse, mutect2, varscan2
- ARAP2 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs952490215, COSV58290800; called by muse, mutect2
- ARHGAP21 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100255885; called by muse, mutect2, varscan2
- ARHGEF15 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs774959863; called by muse, mutect2, varscan2
- ARHGEF16 | c.1193T>C p.F398S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774950266; called by muse, mutect2, varscan2
- ARMC9 | c.180G>A p.K60= | Splice Region (SNP) | VAF 23/94 reads (24%) | catalogued as COSV63019850; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs777911515, COSV63437085; called by muse, mutect2, varscan2
- ASB10 | c.548G>A p.R183H (on ENST00000420175 / NM_001142459.2; = p.R168H on NM_080871.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1363117706; called by muse, mutect2, varscan2
- ATM | c.3375G>C p.L1125F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53754827; called by muse, mutect2, varscan2
- ATP11B | c.917T>A p.I306N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100017765; called by muse, mutect2, varscan2
- ATP6AP1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs781947223; called by muse, mutect2, varscan2
- ATRX | c.6699+1del p.X2233_splice | Splice Site (DEL) | VAF 13/95 reads (14%) | catalogued as COSV64872836; called by mutect2, pindel, varscan2
- AVIL | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs146185696; called by muse, mutect2, varscan2
- B3GAT3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as rs1485574547; called by muse, mutect2, varscan2
- BEND4 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.995); catalogued as COSV101549700, COSV72469149; called by muse, mutect2
- BIVM-ERCC5 | c.2380C>G p.P794A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63244740; called by muse, mutect2, varscan2
- BMP6 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs771664465; called by muse, mutect2, varscan2
- BOC | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs148702312; called by muse, mutect2, varscan2
- BOD1L1 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748162021; called by muse, mutect2, varscan2
- BRAP | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs760917844, COSV59535954; called by muse, varscan2
- BRINP1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs764358377, COSV99775387; called by muse, mutect2, varscan2
- BSN | c.920del p.P307Lfs*52 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as COSV99607095; called by mutect2, varscan2
- BSN | c.10126G>C p.E3376Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV56517794; called by muse, mutect2, varscan2
- C5orf38 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs1429676093; called by muse, mutect2
- CACNA1S | c.3102C>G p.I1034M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV62944484; called by muse, mutect2, varscan2
- CACNA1S | c.2483G>A p.R828K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV100754986, COSV62939128; called by muse, mutect2, varscan2
- CACNA2D3 | c.2984C>T p.S995F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1206255599; called by muse, mutect2, varscan2
- CANT1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.791); catalogued as rs548806863; called by muse, mutect2, varscan2
- CAT | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs573379158, COSV53810779; called by muse, mutect2, varscan2
- CATSPERE | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1193298636; called by muse, mutect2, varscan2
- CAV1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100591935; called by muse, mutect2, varscan2
- CBLB | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.247); catalogued as rs138175657; called by muse, varscan2
- CC2D1A | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs960047029; called by muse, mutect2, varscan2
- CC2D1A | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs377502758; called by muse, mutect2, varscan2
- CC2D1B | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52560021; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC158 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as rs561723655; called by muse, mutect2, varscan2
- CCDC171 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576996401; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs762553129; called by mutect2, varscan2
- CCT3 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375964353; called by muse, mutect2, varscan2
- CCT6A | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV51904596; called by muse, mutect2, varscan2
- CD5L | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63823209; called by muse, mutect2, varscan2
- CDH10 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV52575960; called by muse, mutect2, varscan2
- CDH4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs751765138, COSV64646935; called by muse, mutect2, varscan2
- CELSR1 | c.7817C>T p.S2606L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201155196, COSV99417093; called by muse, mutect2, varscan2
- CELSR3 | c.6436G>A p.V2146I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs199670636; called by muse, mutect2, varscan2
- CENPE | c.3883G>A p.V1295M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs771685356; called by muse, mutect2, varscan2
- CENPE | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54380199; called by muse, mutect2
- CFAP100 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs762502489, COSV61502363; called by muse, mutect2, varscan2
- CFAP251 | c.3226G>A p.V1076I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs781099989, COSV56607922; called by mutect2, varscan2
- CHD3 | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs771700787; called by muse, mutect2, varscan2
- CHD6 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs746149922, COSV58556065; called by muse, mutect2, varscan2
- CHKA | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99694070, COSV99694128; called by muse, mutect2, varscan2
- CLCN2 | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs997463881; called by muse, mutect2, varscan2
- CLEC14A | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60564131; called by muse, mutect2, varscan2
- CLEC16A | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781571686, COSV68497962; called by muse, mutect2, varscan2
- CLIP3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as rs750880445, COSV62112090; called by muse, mutect2, varscan2
- CNGA2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149002674, COSV61704731; called by muse, mutect2, varscan2
- CNGA3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs767999739; called by muse, mutect2, varscan2
- CNTN6 | c.2409A>C p.Q803H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs368055236; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- CORO1B | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as rs767771419, COSV57049917; called by muse, mutect2, varscan2
- CORO6 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs763588603, COSV61470558; called by muse, mutect2, varscan2
- CPSF1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554866754, COSV100574308; called by muse, mutect2, varscan2
- CRMP1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs768763171; called by muse, mutect2, varscan2
- CSMD1 | c.8333A>T p.Q2778L (on ENST00000520002; = p.Q2777L on NM_033225.6) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs745995152; called by muse, mutect2, varscan2
- CSTF2 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100880707; called by muse, mutect2
- CTNND2 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1561136061, COSV58892661; called by muse, mutect2, varscan2
- CUBN | c.4502C>T p.A1501V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs201587209, COSV64712690; called by muse, mutect2, varscan2
- CUL1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57390285; called by muse, mutect2, varscan2
- CWC25 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs201865422; called by muse, mutect2, varscan2
- CYFIP1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs374831208; called by muse, mutect2, varscan2
- CYP2C18 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as COSV99608514; called by muse, mutect2, varscan2
- CYP7B1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1414189844, COSV100043271, COSV59582084; called by muse, mutect2, varscan2
- DCAF12L2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63582303, COSV63584620; called by muse, mutect2, varscan2
- DCLK3 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV69363344; called by muse, mutect2, varscan2
- DDIT3 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs568713877, COSV56252503; called by muse, mutect2, varscan2
- DDX25 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as rs1263512060; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs766714372; called by mutect2, varscan2
- DGKK | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs781821802; called by muse, mutect2, varscan2
- DHRS4L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/156 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV58731636; called by muse, mutect2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX38 | c.3358C>T p.H1120Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51699971; called by muse, mutect2, varscan2
- DIAPH2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as rs1263947677; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as COSV52307798; called by mutect2, pindel, varscan2
- DMRTC2 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782270959, COSV54186844, COSV54187886; called by muse, mutect2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK9 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs750091458, COSV59637175; called by muse, mutect2, varscan2
- DPP6 | c.949G>A p.A317T (on ENST00000377770 / NM_001364500.2; = p.A255T on NM_001936.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370802575, COSV59618705; called by muse, mutect2, varscan2
- DTNB | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749508731, COSV56472198, COSV56475237; called by muse, mutect2, varscan2
- E4F1 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs542965861, COSV57040368; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs369293935; called by mutect2, varscan2
- ECHDC1 | c.712G>A p.E238K (on ENST00000531967 / NM_001139510.1; = p.E232K on NM_001002030.2) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as COSV58933460; called by muse, mutect2, varscan2
- EDNRB | c.493G>A p.D165N (on ENST00000377211 / NM_001201397.1; = p.D75N on NM_000115.5) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1230438816; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.696del p.R233Dfs*65 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs780984426, COSV56182176; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV62569472; called by muse, mutect2, varscan2
- EFCAB6 | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs750468315, COSV53068164; called by muse, mutect2, varscan2
- EHMT1 | c.2921C>T p.T974M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs371580823; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2A | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99855922; called by muse, mutect2, varscan2
- ELL | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs758828885; called by muse, mutect2, varscan2
- EP300 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1280109939, COSV54328681; called by muse, mutect2, varscan2
- EPB41L2 | c.2986G>C p.E996Q | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61352939; called by muse, mutect2, varscan2
- EPHA3 | c.1744C>A p.H582N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100345152; called by muse, mutect2, varscan2
- EPHA5 | c.975C>A p.H325Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV56668369; called by muse, mutect2, varscan2
- ERICH6 | c.589T>A p.C197S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201934751; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs753821453; called by mutect2, varscan2
- ESYT2 | c.2293G>A p.A765T (on ENST00000613624; = p.A689T on NM_020728.3) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs781060682, COSV51752843, COSV99277101; called by muse, mutect2, varscan2
- ETHE1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99415487; called by muse, mutect2
- EVA1A | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs761924250, COSV52059603; called by muse, mutect2, varscan2
- EZR | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1309244595; called by muse, mutect2, varscan2
- F7 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60647635; called by muse, mutect2, varscan2
- F8 | c.6904T>C p.F2302L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM055240; called by muse, mutect2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM171A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747672439; called by muse, mutect2, varscan2
- FAM180A | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs767403406, COSV58528018; called by muse, mutect2, varscan2
- FAM187B | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs975810587; called by muse, mutect2, varscan2
- FAM47A | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as rs774509523, COSV60497662; called by muse, mutect2
- FANCD2OS | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs1178486941, COSV55035199; called by muse, mutect2, varscan2
- FANCF | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59417175; called by muse, mutect2, varscan2
- FASTKD1 | c.245_247del p.K82del | In Frame Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs773553895; called by pindel, varscan2
- FAXC | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV101067170, COSV67602636; called by muse, mutect2, varscan2
- FBXO11 | c.2359G>A p.A787T (on ENST00000403359 / NM_001190274.2; = p.A703T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99315823; called by muse, mutect2, varscan2
- FBXO25 | c.199del p.R67Gfs*44 (on ENST00000382824 / NM_183421.2; = p.G17Efs*6 on NM_012173.3) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs758426962; called by mutect2, pindel, varscan2
- FBXO41 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99721533; called by muse, mutect2, varscan2
- FCRL1 | c.1029C>A p.L343= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as COSV63825097, COSV63827327; called by muse, mutect2, varscan2
- FCRL4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as rs138448208; called by muse, mutect2
- FHL3 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.894); catalogued as rs775433440, COSV99071863; called by muse, mutect2, varscan2
- FKBP10 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100387866; called by muse, mutect2, varscan2
- FKBP8 | c.1061C>T p.A354V (on ENST00000222308 / NM_001308373.2; = p.A355V on NM_012181.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs771523688; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as rs769482947; called by mutect2, varscan2
- FLT4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs762995809, COSV56106480; called by muse, mutect2, varscan2
- FNDC7 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV54757336; called by muse, mutect2
- FSD1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs141559654, COSV99696765; called by muse, mutect2, varscan2
- FSHR | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV58625816; called by muse, mutect2, varscan2
- FUT9 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166504584, COSV56147314; called by muse, mutect2, varscan2
- FYB2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs751231032; called by muse, varscan2
- FZD4 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV72294345; called by muse, mutect2, varscan2
- GABBR2 | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99409259; called by muse, mutect2, varscan2
- GALNT14 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs113322802, COSV61106491; called by muse, mutect2, varscan2
- GCAT | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759488497; called by muse, mutect2, varscan2
- GCDH | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs759176685; called by muse, mutect2, varscan2
- GDA | c.606C>T p.N202= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52997249; called by muse, mutect2, varscan2
- GHDC | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs374649329, COSV56987263; called by muse, mutect2, varscan2
- GON4L | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV55187107; called by muse, mutect2, varscan2
- GPR37L1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs754197349, COSV66162081; called by muse, mutect2
- GRK1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV59552389; called by muse, mutect2, varscan2
- GSDMD | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52797774, COSV52798409; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 24/126 reads (19%) | catalogued as rs754199513; called by mutect2, varscan2
- GULP1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs369009419; called by muse, mutect2, varscan2
- H2AC15 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | catalogued as COSV57586008; called by muse, mutect2, varscan2
- H2BU1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV100797249; called by muse, mutect2, varscan2
- HDLBP | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773848988; called by muse, mutect2, varscan2
- HELZ2 | c.7288G>A p.G2430S (on ENST00000467148 / NM_001037335.2; = p.G1861S on NM_033405.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV64443440; called by muse, mutect2, varscan2
- HFM1 | c.3011A>C p.E1004A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV99646787; called by muse, mutect2, varscan2
- HIP1R | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1381937575; called by muse, mutect2, varscan2
- HOOK2 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99317557; called by muse, mutect2, varscan2
- HOXB9 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1164640901; called by muse, mutect2
- HS6ST2 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63711974; called by muse, mutect2, varscan2
- HSPA13 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs767470993; called by muse, mutect2, varscan2
- HSPB3 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV100115929; called by muse, mutect2, varscan2
- HYDIN | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as COSV55485314; called by muse, mutect2, varscan2
- ICAM3 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244083818; called by muse, mutect2, varscan2
- IDS | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950658, COSV61711118; called by muse, mutect2, varscan2
- IGHV1-46 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | catalogued as rs548625495; called by muse, mutect2, varscan2
- IL37 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.763); catalogued as rs756191994, COSV54491275; called by muse, mutect2, varscan2
- IRX6 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs886809200; called by muse, mutect2, varscan2
- ITSN2 | c.1607A>T p.E536V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61946245; called by muse, mutect2, varscan2
- JAKMIP3 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV53822447, COSV53827987; called by muse, mutect2, varscan2
- JRK | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as COSV101401074; called by muse, mutect2
- KANK2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.263); catalogued as rs1456655097; called by muse, mutect2
- KAT2A | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV52425706; called by muse, mutect2, varscan2
- KATNB1 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782431692; called by muse, mutect2, varscan2
- KCNA1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV101230315, COSV66836858; called by muse, mutect2
- KCND1 | c.1459A>C p.K487Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99501946; called by muse, mutect2
- KCNJ6 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV55723562; called by muse, mutect2, varscan2
- KCNK1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1347757259; called by muse, mutect2, varscan2
- KCNK5 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as rs376599617; called by muse, mutect2, varscan2
- KCNMB3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV99837477; called by muse, mutect2, varscan2
- KCNV1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1313499614, COSV52088317, COSV52088438; called by muse, mutect2, varscan2
- KDM3A | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1293928180, COSV57224726; called by muse, mutect2, varscan2
- KDM5C | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV64765748; called by muse, mutect2, varscan2
- KDM6A | c.2080del p.A694Lfs*21 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as COSV65045427; called by mutect2, pindel, varscan2
- KIF13B | c.2985C>G p.I995M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV72954384; called by muse, mutect2, varscan2
- KIF26A | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as rs201102650, COSV59466497; called by muse, mutect2, varscan2
- KIZ | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99852101; called by muse, mutect2, varscan2
- KLC2 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201517210, COSV57581789; called by muse, mutect2, varscan2
- KLK12 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs563322085; called by muse, mutect2, varscan2
- KMT2A | c.8897C>G p.S2966C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV104417895; called by muse, mutect2, varscan2
- KMT2C | c.2905G>T p.G969* | Nonsense Mutation (SNP) | VAF 20/271 reads (7%) | catalogued as COSV100071738, COSV51427947; called by muse, mutect2
- KMT2C | c.57del p.E20Rfs*85 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV100067709, COSV51402237; called by mutect2, pindel, varscan2
- KRT1 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.554); catalogued as rs1188173810; called by muse, mutect2, varscan2
- KRT10 | c.1361_1363del p.E454del | In Frame Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs1284871067; called by mutect2, pindel, varscan2
- KRTAP27-1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV67001505; called by muse, mutect2, varscan2
- LAMB1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs571064446, COSV99741034; called by muse, mutect2, varscan2
- LANCL2 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99634791; called by muse, mutect2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs746633076; called by mutect2, varscan2
- LDLRAP1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99056331; called by muse, mutect2, varscan2
- LGI4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs762678784; called by muse, mutect2, varscan2
- LINGO4 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369398419, COSV100765053; called by muse, mutect2, varscan2
- LPAR2 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs368960100, COSV99179127; called by muse, mutect2, varscan2
- LRATD1 | c.176del p.P59Rfs*41 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV54472034, COSV99707096; called by mutect2, pindel, varscan2
- LRP1B | c.3962G>T p.G1321V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV101256739; called by muse, mutect2, varscan2
- LRP4 | c.3562del p.E1188Rfs*5 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | catalogued as rs764342618; called by mutect2, pindel, varscan2
- LRPPRC | c.1401A>T p.E467D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1405899908; called by muse, mutect2, varscan2
- LTBP2 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1424526900, COSV100000313, COSV56206352; called by muse, mutect2, varscan2
- MAGEC1 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53578996; called by muse, mutect2, varscan2
- MAN1B1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as rs541409222; called by muse, mutect2, varscan2
- MAP1S | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs746815969, COSV60724705; called by muse, varscan2
- MAP3K10 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768143257, COSV99454347; called by muse, mutect2, varscan2
- MAP3K6 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs199627707; called by muse, mutect2, varscan2
- MAP3K6 | c.826A>T p.I276F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760353235; called by muse, mutect2, varscan2
- MBP | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV62829154; called by muse, mutect2
- MDGA1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs373379741, COSV51796299; called by muse, mutect2, varscan2
- METTL17 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs758407608; called by muse, mutect2, varscan2
- METTL24 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs748963544, COSV58823459; called by muse, mutect2, varscan2
- METTL6 | c.758_760del p.E253del | In Frame Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs753997076; called by pindel, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAT3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs1195606579, COSV57868161; called by muse, mutect2, varscan2
- MISP | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV53118921; called by mutect2, varscan2
- MMP11 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.049); catalogued as rs750098875, COSV53157546; called by muse, mutect2, varscan2
- MORC1 | c.2375C>A p.A792D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99224734; called by muse, mutect2
- MORN5 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201455043, COSV101055787; called by muse, mutect2, varscan2
- MPDZ | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs749987058; called by muse, mutect2, varscan2
- MS4A12 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs757436949, COSV99188883; called by muse, mutect2, varscan2
- MTA1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs782773381, COSV58756839; called by muse, mutect2, varscan2
- MTFR2 | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100886674, COSV100886700; called by mutect2, varscan2
- MUC16 | c.40193G>A p.R13398H | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.369); catalogued as rs764581423, COSV66689492; called by muse, mutect2, varscan2
- MUC17 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776605605, COSV60287564; called by muse, mutect2, varscan2
- MYH2 | c.3093C>G p.I1031M | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV55438292, COSV99819030; called by muse, mutect2, varscan2
- MYH9 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53382462, COSV53382648; called by muse, mutect2, varscan2
- MYO15A | c.5784G>C p.K1928N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768104440; called by muse, mutect2, varscan2
- MYO19 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766865716; called by muse, mutect2, varscan2
- MYO1D | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1366755677, COSV59006869; called by muse, mutect2, varscan2
- MYT1L | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs778352465, COSV101220766; called by muse, mutect2, varscan2
- NAV3 | c.4988G>A p.R1663H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368252063; called by muse, mutect2, varscan2
- NBAS | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs557345395, COSV55712787; called by mutect2, varscan2
- NCAM1 | c.1154T>C p.I385T (on ENST00000316851 / NM_181351.5; = p.I375T on NM_000615.7) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV57523024; called by muse, mutect2, varscan2
- NCOR1 | c.3675T>G p.I1225M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs1309493611; called by muse, mutect2, varscan2
- NFASC | c.1597G>A p.A533T (on ENST00000339876 / NM_001378329.1; = p.A544T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1348968379, COSV100363836; called by muse, mutect2, varscan2
- NFATC1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs780214363, COSV53709752; called by muse, mutect2, varscan2
- NNT | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as CM125558, COSV99239216; called by muse, mutect2
- NOP9 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs759856552, COSV99350647; called by muse, mutect2, varscan2
- NXT1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1568575959; called by muse, mutect2, varscan2
- OR13J1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs569130181, COSV65069499; called by muse, mutect2, varscan2
- OR1Q1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1397350258, COSV52918020, COSV52919601; called by muse, mutect2, varscan2
- OR52L1 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs1291617854; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs746200712; called by mutect2, varscan2
- OSBPL2 | c.1225C>T p.R409C (on ENST00000313733 / NM_144498.4; = p.R397C on NM_014835.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs773593916, COSV100569373, COSV58218898; called by mutect2, varscan2
- OSCP1 | c.1072G>C p.E358Q (on ENST00000356637 / NM_001330493.1; = p.E348Q on NM_145047.5) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV52487872; called by muse, mutect2, varscan2
- OSR1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55345405; called by muse, mutect2, varscan2
- PDE4DIP | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs782311425; called by muse, mutect2, varscan2
- PDSS2 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as rs749571760; called by muse, mutect2
- PINK1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); catalogued as rs756873821, COSV100387242; called by muse, mutect2, varscan2
- PKD1 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs757055929, COSV51919655; called by muse, mutect2, varscan2
- PLCG1 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764393595, COSV54821675; called by muse, mutect2, varscan2
- PLEKHG3 | c.2174C>T p.P725L (on ENST00000394691; = p.P781L on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs773978261, COSV55977995; called by muse, mutect2, varscan2
- PLEKHG6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1413704967, COSV99164972; called by muse, mutect2, varscan2
- PLEKHG7 | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs368328583; called by muse, mutect2, varscan2
- PLXNA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV52531044; called by muse, mutect2, varscan2
- PNPLA7 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs760415144; called by muse, mutect2, varscan2
- POGZ | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99652679; called by muse, mutect2, varscan2
- POM121L12 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.224); catalogued as rs1363726491; called by muse, mutect2, varscan2
- POU2F1 | c.233C>T p.S78L (on ENST00000541643 / NM_001365848.1; = p.S101L on NM_002697.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as rs141034916; called by muse, mutect2, varscan2
- PPM1N | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as rs367762624; called by muse, mutect2, varscan2
- PPP1R32 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.975); catalogued as rs372889299; called by muse, mutect2, varscan2
- PRMT9 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1273215301, COSV100481963; called by muse, mutect2, varscan2
- PRPH | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1438745279; called by muse, mutect2
- PSMA8 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs777581252; called by muse, mutect2, varscan2
- PTPRD | c.4786G>T p.V1596F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644553; called by muse, mutect2, varscan2
- PTPRT | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV61982755; called by muse, mutect2
- QPCTL | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as rs764876367; called by muse, mutect2, varscan2
- QSER1 | c.2128C>T p.H710Y (on ENST00000399302; = p.H839Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV67901561; called by muse, mutect2
- RAB11FIP2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs761769278, COSV62924895; called by muse, mutect2, varscan2
- RAB4A | c.111del p.K37Nfs*10 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs781323910; called by mutect2, varscan2
- RALGAPB | c.3341A>C p.H1114P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99485231; called by muse, mutect2, varscan2
- RAVER1 | c.1097del p.P366Qfs*169 (on ENST00000615032; = p.P366Qfs*141 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/197 reads (12%) | catalogued as rs768618392, COSV53348646; called by mutect2, pindel, varscan2
- RBM10 | c.1578G>A p.S526= | Splice Region (SNP) | VAF 15/70 reads (21%) | catalogued as rs782356345; called by muse, mutect2, varscan2
- RECQL4 | c.2753_2755del p.E918del | In Frame Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs755113079; called by pindel, varscan2
- REST | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750258882; called by muse, mutect2
- RGPD2 | c.3982G>C p.E1328Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100552796; called by muse, mutect2, varscan2
- RHPN1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as rs553239044; called by muse, mutect2, varscan2
- RNF152 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.785); catalogued as rs1465677916; called by muse, mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RPH3A | c.700C>T p.R234C (on ENST00000389385 / NM_001143854.2; = p.R230C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs145114678; called by muse, mutect2, varscan2
- RPL6 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs747383826; called by muse, mutect2, varscan2
- RPN1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs762506765; called by muse, mutect2, varscan2
- RSBN1L | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as rs765531692; called by muse, mutect2, varscan2
- RTTN | c.953G>C p.R318P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55343647; called by muse, mutect2, varscan2
- RUNX3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424371682, COSV100136917; called by muse, mutect2, varscan2
- RYR2 | c.8305G>A p.E2769K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV63682473; called by muse, mutect2, varscan2
- RYR2 | c.8791C>T p.R2931C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs777983238, COSV63676535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.14234G>A p.R4745H (on ENST00000389232; = p.R4746H on NM_001036.6) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165592216, COSV101212583, COSV66802123; called by muse, mutect2, varscan2
- SAFB | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99412583; called by muse, mutect2, varscan2
- SASH3 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368987935, COSV63555985; called by muse, mutect2, varscan2
- SCN10A | c.4280del p.K1427Sfs*2 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs750400627; called by mutect2, varscan2
- SEC23A | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs572679988, COSV56980039; called by muse, mutect2, varscan2
- SEMA4C | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs780410537; called by muse, mutect2, varscan2
- SEMA6B | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs186951396; called by muse, mutect2, varscan2
- SERINC2 | c.596G>A p.R199H (on ENST00000373709 / NM_178865.5; = p.R203H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs374319929; called by muse, mutect2, varscan2
- SH2D3A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs372429785; called by muse, mutect2, varscan2
- SH3RF1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs759409610; called by muse, mutect2, varscan2
- SHANK2 | c.5117G>A p.R1706H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs782013439; called by muse, mutect2, varscan2
- SHC2 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773645712; called by muse, mutect2, varscan2
- SHROOM1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs751016823, COSV60582195; called by muse, mutect2, varscan2
- SHROOM3 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs375262707; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs771414532; called by mutect2, varscan2
- SLC25A11 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900254113; called by muse, mutect2, varscan2
- SLC25A51 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs370897815; called by muse, mutect2, varscan2
- SLC34A2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs775481758; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC8B1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs921953834, COSV99176645; called by muse, mutect2, varscan2
- SLCO2A1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs201131796, COSV100188963; called by muse, mutect2, varscan2
- SLIT2 | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767373337; called by muse, mutect2, varscan2
- SMG6 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300319307, COSV99558166; called by muse, mutect2, varscan2
- SNX32 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV57448940; called by muse, mutect2, varscan2
- SPAM1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532636427, COSV56144434; called by muse, mutect2, varscan2
- SPATA5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as rs1483650172; called by muse, mutect2, varscan2
- SPHKAP | c.3820G>A p.V1274M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs780573652, COSV60882809; called by muse, mutect2, varscan2
- SPOCK2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as rs763573105; called by muse, mutect2, varscan2
- SPPL3 | c.714del p.N240Mfs*85 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs1373051990; called by mutect2, pindel, varscan2
- SPTA1 | c.5281del p.E1761Sfs*19 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV63759163; called by mutect2, pindel, varscan2
- SSR3 | c.420T>G p.Y140* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99411105; called by muse, mutect2
- SSUH2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as rs1385341281; called by muse, mutect2, varscan2
- STK11IP | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs889265612; called by muse, mutect2, varscan2
- STRN3 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1365901575, COSV100670603; called by muse, mutect2, varscan2
- TAB3 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs141293756; called by muse, mutect2, varscan2
- TAF4 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs773858724; called by muse, mutect2, varscan2
- TAS2R42 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62084593; called by muse, mutect2
- TBPL2 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV55973173; called by muse, mutect2, varscan2
- TCTEX1D2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57489599; called by muse, mutect2, varscan2
- TEP1 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1270564509; called by muse, mutect2, varscan2
- TEP1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs760414472; called by muse, mutect2, varscan2
- TGIF2LX | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99033354; called by muse, mutect2, varscan2
- THADA | c.5567C>G p.S1856* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as rs757581612; called by muse, mutect2, varscan2
- TIMM44 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1352281392; called by muse, mutect2, varscan2
- TINAG | c.716del p.N239Ifs*18 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs763463772; called by mutect2, pindel, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs754390908; called by mutect2, varscan2
- TMCO3 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1295039389; called by muse, mutect2, varscan2
- TMEM132B | c.3071T>A p.V1024D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171280; called by muse, mutect2, varscan2
- TMEM187 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs149045617; called by muse, mutect2, varscan2
- TMPRSS12 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs374684282; called by muse, mutect2
- TNFAIP8L2 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV64423305; called by muse, mutect2, varscan2
- TNMD | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100887852; called by muse, mutect2, varscan2
- TNRC6A | c.5782C>A p.L1928M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59361337; called by muse, mutect2, varscan2
- TONSL | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs776417303; called by muse, mutect2, varscan2
- TRAPPC9 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760718123, COSV66906862, COSV66908436; called by mutect2, varscan2
- TRIM6 | c.-67G>A | Splice Region (SNP) | VAF 10/40 reads (25%) | catalogued as COSV53475502; called by muse, mutect2, varscan2
- TRIML1 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs1167383934, COSV60196057; called by muse, mutect2, varscan2
- TRIP12 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.768); catalogued as rs373429636; called by muse, mutect2, varscan2
- TRPM4 | c.2797_2799del p.F933del | In Frame Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs753722479; called by pindel, varscan2
- TRPV6 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 25/97 reads (26%) | catalogued as rs766078262, COSV63891008; called by muse, mutect2, varscan2
- TTC30A | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as rs1470954640; called by muse, mutect2, varscan2
- TTLL5 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs770398766, COSV54032333; called by muse, mutect2
- TTN | c.94537C>T p.R31513C (on ENST00000591111; = p.R24089C on NM_003319.4) | Missense Mutation (SNP) | VAF 39/151 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs143556947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.48462A>C p.E16154D (on ENST00000591111; = p.E8730D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | PolyPhen benign (0); catalogued as rs1447853975; called by muse, mutect2, varscan2
- TYK2 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754899482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5CL | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs967014226, COSV55110631; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs760213136; called by mutect2, varscan2
- UPF2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs745375819, COSV62657811; called by mutect2, varscan2
- USF3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57072749; called by muse, mutect2, varscan2
- USP30 | c.480G>A p.Q160= | Splice Region (SNP) | VAF 18/63 reads (29%) | catalogued as rs1192615519; called by muse, mutect2, varscan2
- USP34 | c.8743G>C p.E2915Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs190691114, COSV101277016; called by mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 21/39 reads (54%) | catalogued as rs764735138; called by mutect2, varscan2
- VOPP1 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV53390629; called by pindel, varscan2
- VSTM1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs752197748, COSV58074858; called by muse, mutect2, varscan2
- WDR38 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs368166491; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK2 | c.5929G>A p.A1977T (on ENST00000297954 / NM_001282394.1; = p.A1940T on NM_006648.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52962045, COSV52965316; called by muse, mutect2, varscan2
- WRN | c.92del p.R31Kfs*17 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV53303797; called by mutect2, pindel, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs762052135; called by mutect2, varscan2
- YBX3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as rs929280330, COSV54385516, COSV54386059; called by muse, mutect2, varscan2
- YJU2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.37); catalogued as rs373312593, COSV53605530; called by mutect2, varscan2
- ZC3H10 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs749310258, COSV57769344, COSV57769616; called by muse, mutect2, varscan2
- ZC3H13 | c.2988dup p.G997Rfs*8 | Frame Shift Ins (INS) | VAF 10/55 reads (18%) | catalogued as rs1427142993; called by mutect2, varscan2
- ZFP14 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1338780867; called by muse, mutect2, varscan2
- ZFPL1 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs747350506, COSV51869651; called by muse, mutect2, varscan2
- ZFR2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1216066273; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs780349586, COSV58743319; called by muse, mutect2, varscan2
- ZNF157 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65659652; called by muse, mutect2, varscan2
- ZNF211 | c.1078C>T p.R360C (on ENST00000347302 / NM_198855.4; = p.R373C on NM_006385.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.567); catalogued as rs766356848; called by muse, mutect2, varscan2
- ZNF219 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV53878840, COSV53884509; called by muse, mutect2, varscan2
- ZNF256 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777092815, COSV99990815; called by muse, mutect2, varscan2
- ZNF358 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as rs1488098262, COSV51174248, COSV51183202; called by muse, mutect2, varscan2
- ZNF382 | c.1381del p.E461Kfs*84 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as COSV53086628, COSV53090943; called by mutect2, pindel, varscan2
- ZNF433 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.622); catalogued as rs764393280, COSV61398349; called by muse, mutect2, varscan2
- ZNF579 | c.1676del p.G559Afs*16 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | catalogued as rs1266986153; called by mutect2, pindel, varscan2
- ZNF587 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV100299474; called by muse, mutect2, varscan2
- ZNF697 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs767011427, COSV70284294; called by muse, mutect2, varscan2
- ZNF7 | c.692del p.K231Sfs*59 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs1398210459; called by mutect2, pindel, varscan2
- ZNF70 | c.242del p.P81Qfs*26 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as rs775749922; called by mutect2, pindel, varscan2
- ZNF808 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV63120365; called by muse, mutect2, varscan2
- ZSCAN22 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs375568613; called by muse, mutect2, varscan2
- ABCA5 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ABCA9 | c.1959G>T p.R653S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- ABCB1 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC020907.6 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ACP7 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSL4 | c.1324G>T p.G442* (on ENST00000340800 / NM_022977.2; = p.G401* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ACTA1 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADAMTS12 | c.4665G>A p.M1555I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS20 | c.4985A>C p.K1662T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ADGRF5 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- AGAP3 | c.355G>C p.E119Q (on ENST00000622464; = p.E155Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGFG1 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AHRR | c.1931G>A p.C644Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- AKAP12 | c.4761C>A p.S1587R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ALAD | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ALG13 | c.1228T>C p.Y410H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ALG13 | c.1365G>T p.K455N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALG6 | c.1228_1229del p.K410Dfs*3 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- ALPI | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL1 | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANGPTL5 | c.872_873insC p.K291Nfs*4 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- ANK2 | c.5791G>C p.G1931R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- ANKRD17 | c.3985G>C p.D1329H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AOC1 | c.2194G>C p.E732Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AOC3 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP2B1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APH1B | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARFGAP3 | c.896dup p.N299Kfs*3 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- ARFGEF1 | c.4561G>A p.D1521N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARFGEF2 | c.1909T>G p.F637V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARFGEF3 | c.6049G>A p.A2017T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARHGAP28 | c.1885T>G p.S629A (on ENST00000383472 / NM_001366230.1; = p.S470A on NM_001010000.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ARHGAP32 | c.4015C>T p.Q1339* (on ENST00000310343 / NM_001378025.1; = p.Q990* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2
- ARHGEF9 | c.464T>G p.I155S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID2 | c.3779A>G p.E1260G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARL4A | c.574del p.M192Cfs*30 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- ARL5A | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARSK | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ARX | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.264); called by muse, mutect2
- ASIC3 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP10D | c.3778A>T p.I1260F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8B3 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ATPSCKMT | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ATXN7 | c.1600T>G p.Y534D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by pindel, varscan2
- BARHL2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- BAZ2B | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BBX | c.1601G>C p.R534T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- BCLAF3 | c.1369C>A p.L457I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- BCOR | c.3787G>T p.E1263* (on ENST00000378444 / NM_001123385.2; = p.E1229* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- BCS1L | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.103); called by muse, mutect2
- BOD1L1 | c.869T>G p.I290S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BOLL | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- BPI | c.474G>T p.K158N (on ENST00000262865; = p.K154N on NM_001725.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- BRAP | c.861C>A p.F287L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- BRD4 | c.3767G>A p.R1256Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- BRPF3 | c.1570C>A p.H524N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- BUB1 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- BUB1 | c.114T>G p.F38L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- BUD13 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf3 | c.*-1G>A | Splice Site (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- CACNB4 | c.828G>C p.K276N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACUL1 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAD | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CAD | c.4916C>T p.A1639V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CAMSAP3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CAPN6 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPZA1 | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CC2D1A | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CCDC151 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC185 | c.1814T>G p.L605R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CCDC191 | c.396G>C p.L132F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CCDC91 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | called by muse, varscan2
- CD14 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CD6 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CD8B | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDC40 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH19 | c.2126A>T p.D709V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDT1 | c.352-1G>T p.X118_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- CEBPZ | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPE | c.1707T>A p.Y569* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- CEP135 | c.1771A>T p.K591* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- CEP152 | c.5060C>T p.S1687L (on ENST00000380950 / NM_001194998.2; = p.S1631L on NM_014985.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CEP170 | c.3254C>T p.S1085L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHD7 | c.4390C>G p.L1464V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHKA | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHRM2 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- CHUK | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- CIC | c.1526del p.P509Hfs*14 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- CLCC1 | c.1576G>C p.D526H (on ENST00000356970 / NM_001377464.1; = p.D476H on NM_015127.5) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCNKA | c.68del p.G23Afs*17 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- CLDN10 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CLEC1B | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CLK2 | c.486A>T p.R162= (on ENST00000368361 / NM_001294339.2; = p.R161= on NM_003993.4) | Splice Region (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- CLTCL1 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CMYA5 | c.5661T>G p.I1887M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CNOT2 | c.746T>G p.I249R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNOT3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL18A1 | c.1400del p.P467Rfs*72 (on ENST00000359759 / NM_130444.3; = p.P232Rfs*72 on NM_030582.4) | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- COL24A1 | c.1688del p.P563Lfs*42 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- COMMD2 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- COPE | c.712C>A p.L238M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- COPS3 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CPNE4 | c.886T>G p.F296V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CREB3L3 | c.750A>C p.K250N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRISP2 | c.490T>G p.Y164D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CSGALNACT2 | c.1613G>T p.S538I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD3 | c.3158dup p.N1053Kfs*12 (on ENST00000297405 / NM_001363185.1; = p.N949Kfs*12 on NM_052900.3) | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, varscan2
- CTR9 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CTTNBP2 | c.2179T>G p.S727A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTTNBP2NL | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CYLD | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYTH3 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- DAPK3 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DCAF1 | c.3655C>G p.L1219V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DCBLD2 | c.853T>C p.F285L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DCLRE1C | c.1148G>A p.R383Q (on ENST00000378278 / NM_001350965.2; = p.R268Q on NM_022487.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCUN1D3 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEFB1 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKH | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.398); called by mutect2, varscan2
- DGKZ | c.1960G>C p.E654Q (on ENST00000454345 / NM_001105540.2; = p.E466Q on NM_003646.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DIAPH3 | c.2485G>C p.E829Q (on ENST00000400324 / NM_001042517.2; = p.E566Q on NM_030932.3) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- DIS3L | c.1193C>T p.S398F (on ENST00000319212 / NM_001143688.3; = p.S315F on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DLGAP1 | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMRT1 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DMXL1 | c.6382T>C p.S2128P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMXL2 | c.2119C>G p.L707V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DNAH11 | c.6299T>G p.F2100C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAH2 | c.10192C>G p.Q3398E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH7 | c.6301C>T p.P2101S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DNAJB6 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- DNAJC13 | c.4965T>G p.F1655L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAJC21 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DPY19L1 | c.541T>A p.L181I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2
- DPYD | c.838T>G p.F280V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- DUSP8 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2
- DUXA | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- EFCAB3 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFNB3 | c.991del p.Q331Rfs*39 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- EGLN2 | c.192del p.R65Efs*86 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- EGR1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ELMO2 | c.895del p.E299Kfs*3 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- ENPP2 | c.2279G>A p.S760N (on ENST00000075322 / NM_001040092.3; = p.S812N on NM_006209.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ENPP2 | c.1513G>A p.E505K (on ENST00000075322 / NM_001040092.3; = p.E557K on NM_006209.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- ERICH3 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ETAA1 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- ETV3L | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EXOC4 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- EXOC8 | c.766T>G p.F256V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- F11R | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FAM120AOS | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM180A | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT3 | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- FBXW8 | c.752G>C p.R251T (on ENST00000309909; = p.R289T on NM_012174.1) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FFAR2 | c.44T>G p.I15S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- FGFBP2 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- FHDC1 | c.3407G>C p.R1136T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FHL5 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FILIP1 | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- FKBP4 | c.372dup p.N125Qfs*7 | Frame Shift Ins (INS) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- FMN2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FPR2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FREM2 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD3 | c.4367G>A p.R1456K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GANAB | c.2597C>T p.S866L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAP43 | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- GLMN | c.1502T>G p.I501S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GLS2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GMFG | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNL2 | c.63A>T p.P21= | Splice Region (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- GNL3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GOLGB1 | c.2616A>T p.E872D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.875); called by muse, varscan2
- GPAT3 | c.1003_1004delinsT p.P335Ffs*16 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by pindel, varscan2*
- GPR107 | c.1609G>C p.V537L (on ENST00000372406 / NM_001136557.2; = p.V489L on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- GPR174 | c.370T>G p.F124V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPR21 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPS1 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- GRIN2B | c.640T>G p.S214A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, varscan2
- GRK3 | c.204T>G p.F68L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- GSPT2 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GTSF1 | c.324T>G p.D108E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- H2AC8 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- H2BW1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HASPIN | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- HCFC1 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HDAC6 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HEPHL1 | c.514T>A p.Y172N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- HERC5 | c.1887C>G p.F629L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HIF1A | c.2050C>G p.H684D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HIRIP3 | c.187-3_187-2del p.X63_splice | Splice Site (DEL) | VAF 28/104 reads (27%) | called by pindel, varscan2
- HMCN1 | c.9948dup p.Y3317Ifs*7 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- HSD17B12 | c.271T>G p.S91A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HSPA1B | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HSPG2 | c.9384G>T p.K3128N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPG2 | c.7043C>G p.S2348C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.408T>G p.N136K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFNAR2 | c.1173G>C p.L391F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- IFNAR2 | c.1296G>C p.L432F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- IGKC | c.324G>C p.*108Yext*59 | Nonstop Mutation (SNP) | VAF 18/72 reads (25%) | called by muse, varscan2
- IL21 | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- INPP4A | c.2272C>A p.L758M (on ENST00000074304 / NM_001134224.1; = p.L719M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- INSC | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- INTS8 | c.1885C>A p.Q629K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO4 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IQCB1 | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IRAK1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITPR2 | c.3368T>C p.V1123A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KCNAB2 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCND2 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- KCNT2 | c.1754T>G p.L585* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- KDM1A | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- KDM6A | c.1715T>G p.F572C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDR | c.2486T>A p.F829Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0100 | c.6308A>G p.D2103G | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF23 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIF4A | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLB | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL1 | c.943T>G p.L315V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KLHL12 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KLHL13 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KLRC4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KREMEN1 | c.142G>T p.A48S (on ENST00000407188; = p.A50S on NM_032045.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- L1CAM | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- LCA5L | c.1996dup p.R666Kfs*19 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- LCP2 | c.343del p.S115Vfs*121 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- LGR5 | c.1339C>G p.H447D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- LGR5 | c.1341C>A p.H447Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.175); called by muse, mutect2
- LILRA5 | c.880del p.Q294Kfs*35 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- LIN9 | c.1690G>C p.D564H (on ENST00000366808 / NM_001270410.2; = p.D509H on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- LMAN2L | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LMBR1L | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- LMNTD1 | c.510A>C p.E170D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONRF1 | c.1948T>A p.L650I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LPAR3 | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRGUK | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- LRRC71 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAB21L1 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MACO1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MAGEB6 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K1 | c.4376C>T p.A1459V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MFSD12 | c.766del p.L256Cfs*30 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- MGAM | c.5542T>G p.F1848V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIOS | c.511_513del p.T171del | In Frame Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- MME | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1572T>G p.I524M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MRTFA | c.1062del p.M355Wfs*82 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- MUSK | c.1825A>C p.K609Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYBPHL | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYH15 | c.2391C>G p.F797L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYLPF | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYOD1 | c.249_250del p.P84Qfs*43 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by pindel, varscan2
- MYRIP | c.1501del p.Q501Sfs*51 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- NADK | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NAXD | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NBEA | c.6861G>T p.Q2287H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NBPF3 | c.1786T>C p.Y596H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- NCAM1 | c.592del p.E198Rfs*11 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- NCBP1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOR2 | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NECAB1 | c.863T>G p.I288S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- NEDD9 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NEUROD1 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- NGFR | c.983-1G>T p.X328_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- NHSL2 | c.2117G>A p.S706N (on ENST00000510661; = p.S1072N on NM_001013627.2) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP11 | c.2965A>T p.R989* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- NMD3 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NOL4 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NOL9 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH2 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPEPPS | c.1705G>T p.V569F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPR1 | c.2538G>T p.E846D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- NRIP1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRROS | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSD1 | c.5107G>C p.E1703Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- NUDT12 | c.48T>G p.F16L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP133 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NUP153 | c.1111A>G p.K371E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUTM2D | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NYNRIN | c.344del p.P115Lfs*4 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- ODC1 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- OGDH | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G9 | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR10H5 | c.871T>G p.F291V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10S1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR2K2 | c.838T>A p.Y280N (on ENST00000374428; = p.Y251N on NM_205859.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR2M5 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4X1 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR8B2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8H3 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBP2 | c.1064A>T p.E355V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OTOGL | c.5057G>T p.C1686F (on ENST00000547103; = p.C1677F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by mutect2, varscan2
- OTOGL | c.6633C>A p.H2211Q (on ENST00000547103; = p.H2202Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OTUD5 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAFAH1B1 | c.1162T>G p.F388V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.07); called by mutect2, varscan2
- PAGR1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PAH | c.572T>G p.F191C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAH | c.306dup p.G103Wfs*6 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- PAPLN | c.3280G>A p.D1094N (on ENST00000554301; = p.D1067N on NM_173462.4) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARD3B | c.2643G>T p.K881N (on ENST00000406610 / NM_001302769.2; = p.K812N on NM_057177.7) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PARD6A | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PARP12 | c.1733A>T p.N578I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP14 | c.4684G>C p.E1562Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PARVB | c.348T>A p.Y116* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- PCDH10 | c.879T>G p.I293M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PCDHB5 | c.534T>A p.F178L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PCDHGA8 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PCLO | c.3320T>G p.L1107* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PCSK5 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PDCD10 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PDCD2L | c.807G>C p.W269C | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDLIM5 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PGAP1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PIK3AP1 | c.160T>G p.S54A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3C3 | c.2474A>T p.D825V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PLXNA3 | c.2763C>A p.D921E | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNA3 | c.4243A>G p.M1415V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLXNA4 | c.2992A>G p.R998G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PNPLA6 | c.2783G>A p.C928Y (on ENST00000414982 / NM_001166111.2; = p.C880Y on NM_006702.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- POLA1 | c.3897+1G>C p.X1299_splice | Splice Site (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- POLQ | c.4851dup p.S1618Ifs*20 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- PPIP5K2 | c.851T>G p.V284G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PRG4 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PRKDC | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- PRR12 | c.822C>A p.Y274* (on ENST00000615927; = p.Y1095* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- PRR14 | c.1280C>G p.S427* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- PRR22 | c.832T>G p.L278V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
460 further variants in this file (141 protein-altering or splice-affecting, 291 silent, 28 other) are not listed here.
